TCGA case TCGA-2G-AAHP — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: Erasmus MC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d7d793f6-eaea-4dd3-8237-c2c02b042340

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Netherlands; Age at index: 31 years; Year of birth: 1967; Vital status: Alive.

Diagnoses (2)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 31.9 years (11,649 days); Year of diagnosis: 1999; Method of diagnosis: Orchiectomy; AJCC staging edition: 5th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IS; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 5,667 days (15.5 years); Ajcc serum tumor markers: S1.
   Pathology details: Intratubular germ cell neoplasia present: Yes; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: No; Timepoint category: Postoperative.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 38 days; Days to treatment end: 56 days; Treatment dose: 26 Gy; Treatment outcome: Complete Response; Number of fractions: 13; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Subsequent primary of the testis (histology not recorded by GDC). Age at diagnosis: 34.1 years (12,465 days); Days to diagnosis: 816 days (2.2 years); Prior treatment: Yes.

Follow-up (3 entries)
- Days to follow up: 5,358 days (14.7 years); Disease response: Tumor Free.
- Days to follow up: 5,667 days (15.5 years); Disease response: Tumor Free.
- Karnofsky performance status: 100; ECOG performance status: 0; Timepoint: Follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day -6: Lactate Dehydrogenase 309; Human Chorionic Gonadotropin 1280.
- Day 36: Lactate Dehydrogenase 279.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Did not attempt to reproduce; Undescended testis history: No.

Family history
- Relative with cancer history: no.
- Relative with cancer history: yes; Relationship type: Grandmother; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Cervical Cancer.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-2G-AAHP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 180 mg.
  Slide TCGA-2G-AAHP-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAHP-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAHP-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-2G-AAHP-05A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-2G-AAHP-05Z: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-2G-AAHP-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History hypospadias: No; Tumor status: Tumor free; New tumor event diagnosis indicator: Yes.
- Postoperative treatment list: Postoperative treatment: Radiation.
- Stage record: AJCC pathologic tumor stage: IS.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves testis only; Intratubular germ cell neoplasm: Present; Lymphovascular invasion: Yes; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS.
- Primary pathology, Pre orchi serum marker info: Pre orchi LDH: 309; Pre orchi hcg: 1280.
- Primary pathology, Post orchi serum marker info: Post orchi LDH: 279.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Testes.
- Follow-up form 1: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: Yes.
- Follow-up form 2: Lost to follow-up: No; Post orchi lymph node dissection: No; Tumor status: Tumor free; Treatment outcome first course: No Measureable Tumor or Tumor Markers; New tumor event diagnosis indicator: Yes.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 5,667 days; disease-specific survival: no event (censored), 5,667 days; disease-free interval: event (new tumor event after initially disease-free), 816 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 816 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAHP-01A-12D-A42X-01): tumor purity 0.88, ploidy 2.81, whole-genome doublings 1.
Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-2G-AAHP-05A-11D-A42X-01): tumor purity 0.42, ploidy 3.45, whole-genome doublings 1.
